Somatic mutation profile of tumor specimen TCGA-42-2591-01A (aliquot TCGA-42-2591-01A-01D-1526-09) from TCGA case TCGA-42-2591, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: GX; Age at diagnosis: 51.1 years (18,654 days).
Specimen TCGA-42-2591-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe089740-99f3-4da4-9f9f-cf9fb9e5c83f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-42-2591-10A (Blood Derived Normal), aliquot TCGA-42-2591-10A-01D-1526-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/924c93ea-8312-4397-80c3-909c88b6adce

The open-access MAF lists 78 somatic variants for this specimen: 58 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 19, In Frame Del 4, Nonsense Mutation 1, In Frame Ins 1, RNA 1, Translation Start Site 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 150/161 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs80357287, CM021503, CM129088, COSV58798164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 165/208 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 137/314 reads (44%) | catalogued as COSV104426763, COSV63978633; called by muse, mutect2, varscan2
- AHNAK | c.15215A>G p.K5072R | Missense Mutation (SNP) | VAF 88/165 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144349823; called by muse, mutect2, varscan2
- ALOX12 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 104/125 reads (83%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV52348782; called by muse, mutect2, varscan2
- ARAP2 | c.4657A>G p.I1553V | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as rs1223920711, COSV58293363; called by muse, mutect2, varscan2
- C21orf58 | c.806C>A p.A269D | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as COSV52450893; called by muse, mutect2, varscan2
- C8orf34 | c.1093A>G p.M365V | Missense Mutation (SNP) | VAF 142/326 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.915); catalogued as COSV61399038; called by muse, mutect2, varscan2
- CDH19 | c.1917C>A p.F639L | Missense Mutation (SNP) | VAF 109/136 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV50980393; called by muse, mutect2, varscan2
- CNN3 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 153/249 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as COSV64637669; called by muse, mutect2, varscan2
- COL7A1 | c.3190G>C p.D1064H | Missense Mutation (SNP) | VAF 76/93 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60404072; called by muse, mutect2, varscan2
- CPSF3 | c.1926A>T p.K642N | Missense Mutation (SNP) | VAF 236/542 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV53012255; called by muse, mutect2, varscan2
- DLG3 | c.1030C>G p.L344V | Missense Mutation (SNP) | VAF 123/282 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV52087868; called by muse, mutect2, varscan2
- DMKN | c.363T>G p.I121M | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV60090597; called by muse, mutect2, varscan2
- DNAH8 | c.3079G>C p.A1027P | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.284); catalogued as COSV59484451; called by muse, mutect2, varscan2
- ETV3L | c.516G>T p.Q172H | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.06); catalogued as COSV71901226; called by muse, mutect2, varscan2
- FLII | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100493677, COSV58948502; called by muse, mutect2, varscan2
- GABRA4 | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 266/605 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV51936147; called by muse, mutect2, varscan2
- GABRQ | c.237A>G p.G79= | Splice Region (SNP) | VAF 110/271 reads (41%) | catalogued as COSV64784202; called by muse, mutect2, varscan2
- GRM6 | c.2255T>G p.I752S | Missense Mutation (SNP) | VAF 78/91 reads (86%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV51450504; called by muse, mutect2, varscan2
- HNRNPA1 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV52939104; called by muse, mutect2, varscan2
- IFNAR2 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 91/221 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.133); catalogued as COSV51618459; called by muse, mutect2, varscan2
- JAGN1 | c.513C>A p.D171E | Missense Mutation (SNP) | VAF 174/489 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV57063057; called by muse, mutect2, varscan2
- KLF9 | c.635T>G p.F212C | Missense Mutation (SNP) | VAF 94/293 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65808280; called by muse, mutect2, varscan2
- KLHL32 | c.781G>T p.V261F | Missense Mutation (SNP) | VAF 175/219 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV65115347; called by muse, mutect2, varscan2
- KPNA6 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as rs767067967, COSV65362342; called by muse, mutect2, varscan2
- LAMA1 | c.514C>G p.P172A | Missense Mutation (SNP) | VAF 106/131 reads (81%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101056774, COSV67545150; called by muse, mutect2, varscan2
- LRIG1 | c.911G>A p.S304N | Missense Mutation (SNP) | VAF 63/100 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs756519144, COSV56242232; called by muse, mutect2, varscan2
- LRP2BP | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 82/104 reads (79%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1430189645, COSV60751106, COSV60751182; called by muse, mutect2, varscan2
- LZTR1 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 81/99 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53152282; called by muse, mutect2, varscan2
- MAP3K5 | c.749G>A p.C250Y | Missense Mutation (SNP) | VAF 171/220 reads (78%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as COSV62889128; called by muse, mutect2, varscan2
- MED14 | c.2464A>G p.I822V | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.651); catalogued as COSV61358816; called by muse, mutect2, varscan2
- MMRN1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV53343352; called by muse, mutect2, varscan2
- MORF4L2 | c.722A>C p.Y241S | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.375); catalogued as COSV64611525; called by muse, mutect2, varscan2
- MS4A5 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 171/407 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.066); catalogued as rs142678653; called by muse, mutect2, varscan2
- OR51D1 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 152/185 reads (82%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV62914471, COSV62914925; called by muse, mutect2, varscan2
- OSBPL1A | c.2751G>C p.R917S (on ENST00000319481 / NM_080597.4; = p.R404S on NM_018030.4) | Missense Mutation (SNP) | VAF 71/89 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59112992; called by muse, mutect2, varscan2
- PHACTR3 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 66/201 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.072); catalogued as rs747934926, COSV63025654; called by muse, mutect2, varscan2
- PLEKHN1 | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.079); catalogued as COSV58533849; called by muse, mutect2, varscan2
- PLPPR4 | c.2185C>T p.R729W | Missense Mutation (SNP) | VAF 130/189 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1443444318, COSV64567875; called by muse, mutect2, varscan2
- PNPLA6 | c.2863_2865del p.K955del (on ENST00000414982 / NM_001166111.2; = p.K907del on NM_006702.5) | In Frame Del (DEL) | VAF 17/19 reads (89%) | catalogued as rs1399899690; called by mutect2, varscan2
- PRSS55 | c.717G>C p.K239N | Missense Mutation (SNP) | VAF 177/405 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.281); catalogued as COSV60809482; called by muse, mutect2, varscan2
- RBBP5 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 159/195 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1341351018, COSV99196813; called by muse, mutect2, varscan2
- RNF213 | c.9148G>A p.V3050M | Missense Mutation (SNP) | VAF 187/209 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs1480754370, COSV60410419; called by muse, mutect2, varscan2
- SLC30A5 | c.1324A>C p.S442R | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67450716; called by muse, mutect2, varscan2
- SORL1 | c.6109G>T p.D2037Y | Missense Mutation (SNP) | VAF 133/371 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99493987; called by muse, mutect2, varscan2
- SORL1 | c.6110A>G p.D2037G | Missense Mutation (SNP) | VAF 133/373 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.94); catalogued as COSV99493991; called by muse, mutect2, varscan2
- TAB3 | c.225C>A p.N75K | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55841414; called by muse, mutect2
- TACC2 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as COSV100551660, COSV57751028; called by muse, mutect2, varscan2
- TENM1 | c.6517A>T p.S2173C | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64445456; called by muse, mutect2, varscan2
- TMEM59 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as rs1335450402, COSV52376259; called by muse, mutect2, varscan2
- TNRC6A | c.2972C>A p.S991Y | Missense Mutation (SNP) | VAF 77/175 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59370795; called by muse, mutect2, varscan2
- XIAP | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63024185; called by muse, mutect2, varscan2
- ATP1B1 | c.624_632del p.L209_V211del | In Frame Del (DEL) | VAF 91/285 reads (32%) | called by mutect2, pindel, varscan2
- FOXD4L4 | c.216_218dup p.E72_H73insQ | In Frame Ins (INS) | VAF 30/166 reads (18%) | called by pindel, varscan2
- KIR2DL3 | c.100_112del p.H34Wfs*2 | Frame Shift Del (DEL) | VAF 139/612 reads (23%) | called by mutect2, pindel, varscan2
- UGGT1 | c.321_332del p.F107_S111delinsL | In Frame Del (DEL) | VAF 69/246 reads (28%) | called by mutect2, pindel, varscan2
- XYLT1 | c.2512_2550del p.L838_I850del | In Frame Del (DEL) | VAF 56/91 reads (62%) | called by mutect2, pindel
- ATF6 | c.714T>G p.P238= | Silent (SNP) | VAF 121/238 reads (51%) | catalogued as COSV63410423; called by muse, mutect2, varscan2
- BCL7B | c.423G>A p.Q141= | Silent (SNP) | VAF 340/778 reads (44%) | catalogued as COSV56271562, COSV99790295; called by muse, mutect2, varscan2
- CEP250 | c.3943C>T p.L1315= | Silent (SNP) | VAF 64/173 reads (37%) | catalogued as COSV61175125; called by muse, mutect2, varscan2
- CNTRL | c.825G>T p.L275= | Silent (SNP) | VAF 11/216 reads (5%) | catalogued as COSV99442479; called by muse, mutect2
- COL1A2 | c.1245C>T p.G415= | Silent (SNP) | VAF 76/169 reads (45%) | catalogued as rs752359132, COSV51958095, COSV51960154; called by muse, mutect2, varscan2
- EDA | c.726A>T p.G242= | Silent (SNP) | VAF 264/635 reads (42%) | catalogued as COSV65785786; called by muse, mutect2, varscan2
- EZHIP | c.1263C>T p.I421= | Silent (SNP) | VAF 108/236 reads (46%) | catalogued as rs781844509, COSV57957766; called by muse, mutect2, varscan2
- HCRTR2 | c.468C>T p.I156= | Silent (SNP) | VAF 150/322 reads (47%) | catalogued as COSV63794015, COSV63798243; called by muse, mutect2, varscan2
- ITGAE | c.2259G>A p.R753= | Silent (SNP) | VAF 138/184 reads (75%) | catalogued as COSV54000158; called by muse, mutect2, varscan2
- LHFPL4 | c.57G>C p.S19= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as COSV55005215; called by muse, varscan2
- NBL1 | c.315G>C p.V105= | Silent (SNP) | VAF 44/86 reads (51%) | catalogued as COSV57031609; called by muse, mutect2, varscan2
- PRKD1 | c.2085G>A p.R695= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV59588096; called by muse, mutect2, varscan2
- RBBP5 | c.1518G>A p.G506= | Silent (SNP) | VAF 159/196 reads (81%) | catalogued as COSV99196815; called by muse, mutect2, varscan2
- RUNX1 | c.1221C>T p.N407= (on ENST00000344691 / NM_001001890.3; = p.N434= on NM_001754.5) | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV55895719; called by muse, mutect2, varscan2
- SHCBP1 | c.1422A>T p.S474= | Silent (SNP) | VAF 101/265 reads (38%) | catalogued as COSV57650680; called by muse, mutect2, varscan2
- SMC5 | c.1551A>G p.Q517= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as rs1240735828, COSV63195874; called by muse, mutect2, varscan2
- SUCLG1 | c.45C>T p.V15= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs949898726, COSV67266047; called by muse, mutect2, varscan2
- SYNJ2 | c.2670C>T p.A890= | Silent (SNP) | VAF 188/243 reads (77%) | catalogued as COSV62901245; called by muse, mutect2, varscan2
- TEX10 | c.1092C>T p.S364= | Silent (SNP) | VAF 88/276 reads (32%) | catalogued as COSV66519036; called by muse, mutect2, varscan2
- HERC2P3 | n.426G>T | RNA (SNP) | VAF 169/596 reads (28%) | catalogued as rs780056731; called by muse, mutect2, varscan2
